Somatic mutation profile of tumor specimen TARGET-10-PARAUE-09A (aliquot TARGET-10-PARAUE-09A-01D) from TARGET case TARGET-10-PARAUE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,223 days).
Specimen TARGET-10-PARAUE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eac1f115-1d80-470c-a763-3e7fa3c5367e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAUE-14A (Bone Marrow Normal), aliquot TARGET-10-PARAUE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cee263f3-e853-4163-81e2-ea03d6d7ca4b

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, RNA 2, Intron 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DOCK8 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs375758495; called by muse, mutect2, varscan2
- DOT1L | c.973T>A p.Y325N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67112195; called by muse, mutect2, varscan2
- GRXCR1 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 13/196 reads (7%) | catalogued as rs772625515, COSV67671175; called by muse, mutect2
- PLEKHS1 | c.466C>G p.L156V (on ENST00000369310 / NM_182601.1; = p.L162V on NM_024889.5) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); catalogued as COSV63054530; called by muse, mutect2
- SETD2 | c.4587-1G>C p.X1529_splice | Splice Site (SNP) | VAF 37/200 reads (19%) | catalogued as COSV57441077; called by muse, mutect2, varscan2
- DCLRE1A | c.2488_2489del p.Q830Efs*13 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by pindel*, varscan2
- EPHA4 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRM | c.2798T>A p.I933N | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RADX | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFHX2 | c.5894C>T p.A1965V | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP32 | c.5142C>T p.N1714= (on ENST00000310343 / NM_001378025.1; = p.N1365= on NM_014715.4) | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1469836985; called by muse, mutect2, varscan2
- NLRC4 | c.1224C>T p.F408= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs761437489, COSV61591170; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA5 | c.468G>A p.A156= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as rs782058529, COSV65349449; called by muse, mutect2
- SLC25A13 | c.1794G>A p.L598= | Silent (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- GALNT13 | c.1531-3697T>G | Intron (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- GBAP1 | n.99T>C | RNA (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- PPIAP80 | n.276G>A | RNA (SNP) | VAF 13/67 reads (19%) | catalogued as rs370620833; called by muse, mutect2, varscan2
- RHOT2 | c.*461G>A | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs768668596; called by muse, mutect2, varscan2
- TTC12 | c.445-243G>A | Intron (SNP) | VAF 10/79 reads (13%) | catalogued as rs782300102; called by muse, mutect2, varscan2
